Somatic mutation profile of tumor specimen MMRF_1639_1_BM_CD138pos (aliquot MMRF_1639_1_BM_CD138pos_T1_KBS5U_L04309) from MMRF case MMRF_1639, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.3 years (24,581 days).
Specimen MMRF_1639_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4eeb0ece-66f9-4fb2-a032-14a5fad284e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1639_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1639_1_PB_Whole_C3_KBS5U_L04320; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1f9e8e9-06d1-473b-b38e-f164b8aa20ae

The open-access MAF lists 108 somatic variants for this specimen: 51 protein-altering or splice-affecting, 13 silent, 44 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, 3'UTR 28, Silent 13, Intron 10, Nonsense Mutation 6, Splice Site 3, 5'UTR 3, Splice Region 2, 3'Flank 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 11/60 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- BMERB1 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs202088138, COSV55508280; called by muse, mutect2, varscan2
- C14orf93 | c.1337G>A p.R446H | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs143379381; called by muse, mutect2, varscan2
- CDH12 | c.941G>C p.G314A | Missense Mutation (SNP) | VAF 76/281 reads (27%) | SIFT tolerated (0.95); PolyPhen probably damaging (0.999); catalogued as COSV66426630; called by muse, mutect2, varscan2
- CDH7 | c.1897C>T p.R633W | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs562336351; called by muse, mutect2, varscan2
- CDH8 | c.1536+6T>G | Splice Region (SNP) | VAF 58/107 reads (54%) | catalogued as COSV54848692; called by muse, mutect2, varscan2
- COL6A5 | c.6898C>T p.Q2300* (on ENST00000312481; = p.Q2296* on NM_153264.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/76 reads (11%) | catalogued as COSV99592223; called by muse, mutect2, varscan2
- CR1 | c.401+6T>C | Splice Region (SNP) | VAF 21/75 reads (28%) | catalogued as rs187655279; called by muse, mutect2, varscan2
- CTPS1 | c.1126C>T p.R376* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV65452748; called by muse, mutect2, varscan2
- GK | c.520C>G p.L174V | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.067); catalogued as COSV66735438; called by muse, mutect2
- HEPACAM2 | c.364G>A p.V122M (on ENST00000394468 / NM_001039372.4; = p.V110M on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs139218067; called by muse, mutect2, varscan2
- IGHV1-69D | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.07); catalogued as rs1283966798; called by muse, varscan2
- IGHV2-70 | c.250C>A p.L84M | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs573185871; called by muse, varscan2
- IGHV2-70D | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1169792576; called by muse, varscan2
- IGHV4-39 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as rs190955722; called by muse, varscan2
- IGKV1-5 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as rs572469357; called by muse, mutect2
- IGKV1-5 | c.304C>G p.P102A | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.048); catalogued as rs546309985; called by muse, mutect2
- IGKV4-1 | c.338A>C p.Y113S | Missense Mutation (SNP) | VAF 22/23 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1141253; called by muse, varscan2
- IGLV3-1 | c.250A>T p.N84Y | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs369317662; called by muse, varscan2
- LAMB1 | c.1069G>A p.V357I | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as rs200303288; called by muse, mutect2, varscan2
- MUSK | c.1415G>T p.S472I | Missense Mutation (SNP) | VAF 13/277 reads (5%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.467); catalogued as rs1253803059; called by muse, mutect2
- OR12D1 | c.118A>G p.N40D | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201775217; called by muse, mutect2
- OSCP1 | c.955C>T p.R319W (on ENST00000356637 / NM_001330493.1; = p.R309W on NM_145047.5) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1406005863; called by muse, mutect2, varscan2
- RAD9B | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs1439336615, COSV63778564; called by muse, mutect2, varscan2
- RFX2 | c.1969G>A p.V657I | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.682); catalogued as rs1015514275; called by muse, mutect2, varscan2
- RHOU | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 70/111 reads (63%) | catalogued as rs745690593; called by muse, mutect2, varscan2
- SCN9A | c.937C>G p.L313V | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1060502050; ClinVar: uncertain significance; called by muse, mutect2
- SLC16A9 | c.830A>G p.Y277C | Missense Mutation (SNP) | VAF 68/124 reads (55%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.455); catalogued as rs747080169; called by muse, mutect2, varscan2
- SPRED1 | c.767G>T p.R256L | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.758); catalogued as COSV54434997; called by muse, mutect2, varscan2
- THSD7B | c.715T>C p.Y239H | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.028); catalogued as rs1471236067; called by muse, mutect2, varscan2
- ANXA6 | c.554A>G p.Y185C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- BDP1 | c.6995+1G>A p.X2332_splice | Splice Site (SNP) | VAF 62/203 reads (31%) | called by muse, mutect2, varscan2
- BRDT | c.323A>T p.Y108F | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- BRWD3 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- C17orf80 | c.1505T>G p.L502R | Missense Mutation (SNP) | VAF 50/177 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CLCN1 | c.1850C>A p.S617* | Nonsense Mutation (SNP) | VAF 46/144 reads (32%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.206T>A p.L69H | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, varscan2
- IRAK1 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITK | c.713A>C p.E238A | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- LRRC4 | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.235); called by muse, mutect2
- LYZL1 | c.515G>A p.W172* (on ENST00000375500; = p.W126* on NM_032517.6) | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2, varscan2
- MAP3K7 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NONO | c.106C>A p.P36T | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PDSS1 | c.1108-1G>C p.X370_splice | Splice Site (SNP) | VAF 37/76 reads (49%) | called by muse, mutect2, varscan2
- SP140 | c.2362-1G>T p.X788_splice | Splice Site (SNP) | VAF 5/11 reads (45%) | called by mutect2, varscan2
- SYNRG | c.1868T>C p.V623A | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.061); called by muse, mutect2
- UBR5 | c.7962G>A p.M2654I | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- USH2A | c.859G>T p.E287* | Nonsense Mutation (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- WNT8A | c.118A>T p.T40S | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.85); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ZNF76 | c.1642A>C p.N548H | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.054); called by muse, varscan2
- ZNF761 | c.1046C>T p.T349I | Missense Mutation (SNP) | VAF 10/316 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2
- DUSP2 | c.414C>T p.C138= | Silent (SNP) | VAF 24/43 reads (56%) | catalogued as COSV56619333; called by muse, mutect2, varscan2
- DUSP2 | c.252G>A p.E84= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs768266724, COSV56619478; called by muse, varscan2
- FREM1 | c.5736G>T p.R1912= | Silent (SNP) | VAF 22/124 reads (18%) | called by muse, mutect2, varscan2
- GK | c.522T>A p.L174= | Silent (SNP) | VAF 17/58 reads (29%) | called by muse, mutect2
- IGHV2-70D | c.156A>T p.G52= | Silent (SNP) | VAF 22/76 reads (29%) | called by muse, varscan2
- KIF1B | c.3387C>A p.I1129= (on ENST00000377086 / NM_001365952.1; = p.I1083= on NM_015074.3) | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV99823906; called by muse, mutect2
- KIF5B | c.2181A>G p.A727= | Silent (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2
- LINGO3 | c.1614C>T p.F538= | Silent (SNP) | VAF 48/147 reads (33%) | called by muse, mutect2, varscan2
- PCDHAC1 | c.1362T>A p.V454= | Silent (SNP) | VAF 10/64 reads (16%) | called by muse, mutect2, varscan2
- PCDHB2 | c.1335C>T p.D445= | Silent (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- PRDM15 | c.1320C>T p.C440= | Silent (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2
- PTGER3 | c.378G>C p.S126= | Silent (SNP) | VAF 9/91 reads (10%) | catalogued as COSV60690239, COSV60696037; called by muse, mutect2, varscan2
- SNX21 | c.261C>T p.L87= | Silent (SNP) | VAF 3/43 reads (7%) | catalogued as COSV61132897; called by muse, mutect2
- ABI3BP | c.-14G>A | 5'UTR (SNP) | VAF 7/69 reads (10%) | called by muse, mutect2, varscan2
- ARNTL2 | chr12:27422929 T>C | 3'Flank (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- ATP6V0A2 | c.1038+119C>G | Intron (SNP) | VAF 7/15 reads (47%) | catalogued as rs1401701760; called by muse, mutect2, varscan2
- CLSTN1 | c.*925C>T | 3'UTR (SNP) | VAF 6/57 reads (11%) | called by muse, mutect2, varscan2
- CNOT3 | c.-50-1439G>A | Intron (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- COL13A1 | c.-240C>T | 5'UTR (SNP) | VAF 23/43 reads (53%) | called by muse, mutect2, varscan2
- CSNK1G3 | c.*92C>T | 3'UTR (SNP) | VAF 15/181 reads (8%) | catalogued as rs1281991658; called by muse, mutect2
- CTNND1 | c.*2769G>C | 3'UTR (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- DEK | c.*564T>C | 3'UTR (SNP) | VAF 5/95 reads (5%) | called by muse, mutect2
- DMTF1 | c.*870C>T | 3'UTR (SNP) | VAF 6/74 reads (8%) | catalogued as COSV57538061; called by muse, mutect2
- DTL | c.*1559del | 3'UTR (DEL) | VAF 16/97 reads (16%) | called by mutect2, pindel, varscan2
- DZIP1 | c.*2519G>T | 3'UTR (SNP) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- EHF | c.*1852G>T | 3'UTR (SNP) | VAF 14/29 reads (48%) | called by muse, mutect2, varscan2
- EIF4E1B | c.297-87G>A | Intron (SNP) | VAF 4/12 reads (33%) | catalogued as rs535773603; called by mutect2, varscan2
- EIF5A2 | c.*3279A>G | 3'UTR (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
- FAM169A | c.*1725A>G | 3'UTR (SNP) | VAF 29/105 reads (28%) | catalogued as rs1010562892; called by muse, mutect2, varscan2
- FLT4 | c.*946C>T | 3'UTR (SNP) | VAF 5/83 reads (6%) | called by muse, mutect2
- FMO5 | c.-38+9C>A | Intron (SNP) | VAF 13/21 reads (62%) | called by muse, mutect2, varscan2
- GABRP | c.*223C>T | 3'UTR (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2
- GSR | c.*1G>A | 3'UTR (SNP) | VAF 37/86 reads (43%) | catalogued as rs915133836; called by muse, mutect2, varscan2
- IGF2BP3 | c.*24A>G | 3'UTR (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2, varscan2
- IGFBP5 | c.*4222_*4223insA | 3'UTR (INS) | VAF 24/56 reads (43%) | catalogued as COSV99289058; called by mutect2, pindel, varscan2
- IGFN1 | c.*30C>A | 3'UTR (SNP) | VAF 29/234 reads (12%) | catalogued as COSV99812846; called by muse, mutect2, varscan2
- KIF13A | c.4581+306G>A | Intron (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- LRCH2 | c.*1296T>A | 3'UTR (SNP) | VAF 60/85 reads (71%) | catalogued as rs1246057069; called by muse, mutect2, varscan2
- MIER3 | c.*1336G>C | 3'UTR (SNP) | VAF 50/128 reads (39%) | called by muse, mutect2, varscan2
- MRGPRF | c.48+77C>T | Intron (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- NACC2 | c.*780G>A | 3'UTR (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2, varscan2
- NPY | c.1-132G>T | Intron (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2
- NR2F2 | c.-470G>A | 5'UTR (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2, varscan2
- OR52L2P | n.561C>A | RNA (SNP) | VAF 29/70 reads (41%) | called by muse, mutect2
- PCDH7 | c.*1137T>C | 3'UTR (SNP) | VAF 7/16 reads (44%) | called by muse, varscan2
- PIK3CB | c.*1C>T | 3'UTR (SNP) | VAF 33/301 reads (11%) | catalogued as rs756330302; called by muse, mutect2, varscan2
- RNF19A | c.*488T>G | 3'UTR (SNP) | VAF 40/76 reads (53%) | called by muse, mutect2, varscan2
- RSBN1 | c.*4110_*4114del | 3'UTR (DEL) | VAF 10/44 reads (23%) | catalogued as rs772042986; called by mutect2, pindel
- SPRED2 | c.27-21745A>G | Intron (SNP) | VAF 48/107 reads (45%) | called by muse, varscan2
- ST6GALNAC2 | chr17:76563547 C>T | 3'Flank (SNP) | VAF 176/386 reads (46%) | called by muse, mutect2, varscan2
- TFR2 | c.966+56G>T | Intron (SNP) | VAF 13/106 reads (12%) | called by muse, mutect2, varscan2
- TOX2 | c.*533A>G | 3'UTR (SNP) | VAF 24/51 reads (47%) | catalogued as rs1004443772; called by muse, mutect2, varscan2
- TRIM36 | c.*171G>A | 3'UTR (SNP) | VAF 25/92 reads (27%) | called by muse, mutect2, varscan2
- VCPIP1 | c.*314C>A | 3'UTR (SNP) | VAF 45/83 reads (54%) | catalogued as COSV100125632; called by muse, mutect2, varscan2
- VGLL3 | c.*8873A>T | 3'UTR (SNP) | VAF 15/108 reads (14%) | called by muse, mutect2, varscan2
- YWHAQ | c.*914T>C | 3'UTR (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
- ZCCHC8 | c.200-23T>C | Intron (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2, varscan2
